Somatic mutation profile of tumor specimen BA2068D (aliquot aq-BA2068D) from BEATAML1.0 case 2469, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Primary diagnosis: Acute myeloid leukemia with mutated NPM1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 64.2 years (23,445 days).
Specimen BA2068D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ae73a075-700c-4811-bb45-e60cc243c6e1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2026D (Solid Tissue Normal), aliquot aq-BA2026D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/95a5341f-4ad8-4d58-83d5-3cd5515ce210

The open-access MAF lists 37 somatic variants for this specimen: 26 protein-altering or splice-affecting, 6 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 6, Frame Shift Ins 4, Nonsense Mutation 2, Intron 2, Splice Site 1, Translation Start Site 1, 3'UTR 1, Frame Shift Del 1, 5'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACSM2A | c.1291G>A p.D431N (on ENST00000219054; = p.D352N on NM_001308169.2) | Missense Mutation (SNP) | VAF 48/124 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as rs749299994, COSV54583784; called by muse, mutect2, varscan2
- MED14 | c.2943C>G p.D981E | Missense Mutation (SNP) | VAF 43/103 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV61356918; called by muse, varscan2
- MYBPC3 | c.821C>T p.T274M | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.148); catalogued as rs748746951; called by muse, mutect2, varscan2
- NCR3 | c.407C>T p.A136V | Missense Mutation (SNP) | VAF 53/104 reads (51%) | SIFT tolerated (0.2); PolyPhen benign (0.066); catalogued as COSV99279043; called by muse, mutect2, varscan2
- NPHP4 | c.517C>T p.Q173* | Nonsense Mutation (SNP) | VAF 38/70 reads (54%) | catalogued as rs997408852, CM139126; called by muse, mutect2, varscan2
- NPM1 | c.863_864insCATG p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 23/116 reads (20%) | catalogued as rs1554138188, COSV51544217, COSV51551832, COSV51558469, COSV51558827, COSV51561854; called by mutect2, pindel, varscan2
- PCSK5 | c.3976T>C p.C1326R | Missense Mutation (SNP) | VAF 40/87 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1321297783; called by muse, mutect2, varscan2
- SIGLEC8 | c.1297C>T p.P433S | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.05); catalogued as COSV58476303; called by muse, mutect2, varscan2
- TET2 | c.3646C>T p.R1216* | Nonsense Mutation (SNP) | VAF 91/209 reads (44%) | catalogued as rs1009194427, COSV54398925; called by muse, mutect2, varscan2
- ZNF213 | c.439C>T p.R147W | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.451); catalogued as rs774347813, COSV67727471; called by muse, mutect2, varscan2
- ZNF446 | c.1223C>T p.S408L | Missense Mutation (SNP) | VAF 39/101 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs764456622, COSV59992275; called by muse, mutect2, varscan2
- AP002748.5 | c.542del p.E181Gfs*7 | Frame Shift Del (DEL) | VAF 76/224 reads (34%) | called by mutect2, pindel, varscan2
- EPS8L2 | c.1202G>T p.R401L | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- FCGBP | c.646G>T p.A216S | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.47); called by muse, mutect2
- GALNT6 | c.649G>T p.D217Y | Missense Mutation (SNP) | VAF 39/77 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- H2AC6 | c.350T>A p.L117Q | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- MAP10 | c.274dup p.Q92Pfs*19 | Frame Shift Ins (INS) | VAF 81/220 reads (37%) | called by mutect2, pindel, varscan2
- MUC17 | c.3167G>A p.S1056N | Missense Mutation (SNP) | VAF 66/356 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.246); called by muse, varscan2
- NFIX | c.1153_1154insGGGTGGC p.T385Rfs*40 (on ENST00000592199 / NM_001365902.3; = p.T385Rfs*72 on NM_002501.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 40/129 reads (31%) | called by mutect2, pindel, varscan2
- OR10K1 | c.604C>A p.L202I | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT tolerated (0.95); PolyPhen benign (0.143); called by muse, mutect2
- OR8K5 | c.571A>T p.N191Y | Missense Mutation (SNP) | VAF 42/87 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- PABPC4 | c.136A>T p.M46L | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.44); PolyPhen benign (0.001); called by mutect2, varscan2
- SETD2 | c.7432-4_7439delinsACCTGGGGC p.X2478_splice | Splice Site (DEL) | VAF 40/174 reads (23%) | called by pindel, varscan2*
- SLC22A18AS | c.361T>G p.S121A | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- STK26 | c.973dup p.S325Kfs*10 | Frame Shift Ins (INS) | VAF 70/173 reads (40%) | called by mutect2, pindel, varscan2
- ZNHIT1 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 28/61 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.227); called by muse, mutect2, varscan2
- AEBP1 | c.2205G>A p.S735= | Silent (SNP) | VAF 5/14 reads (36%) | called by muse, mutect2, varscan2
- CA12 | c.664C>A p.R222= | Silent (SNP) | VAF 135/300 reads (45%) | catalogued as COSV51604208, COSV99457980; called by muse, mutect2, varscan2
- DIP2C | c.177G>A p.P59= | Silent (SNP) | VAF 51/113 reads (45%) | catalogued as rs755927736; called by muse, mutect2, varscan2
- GRM5 | c.2421C>T p.S807= | Silent (SNP) | VAF 27/52 reads (52%) | called by muse, mutect2, varscan2
- MYOM2 | c.4314C>T p.H1438= | Silent (SNP) | VAF 25/50 reads (50%) | catalogued as rs745736323, COSV100037998; called by muse, mutect2, varscan2
- VPS18 | c.357G>A p.T119= | Silent (SNP) | VAF 20/37 reads (54%) | called by mutect2, varscan2
- AC002511.3 | n.26C>A | RNA (SNP) | VAF 5/46 reads (11%) | called by muse, mutect2
- KSR2 | c.987-6645G>C | Intron (SNP) | VAF 110/251 reads (44%) | called by muse, mutect2, varscan2
- LZTS2 | c.*416C>A | 3'UTR (SNP) | VAF 4/60 reads (7%) | called by muse, mutect2
- RNA5-8SP2 | chr16:34159614 G>T | 5'Flank (SNP) | VAF 9/23 reads (39%) | called by muse, mutect2, varscan2
- TMEM130 | c.85+547G>A | Intron (SNP) | VAF 37/103 reads (36%) | called by muse, mutect2, varscan2
